Somatic mutation profile of tumor specimen C3L-09396-02 (aliquot CPT0502480006) from CPTAC case C3L-09396, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 68.8 years (25,137 days).
Specimen C3L-09396-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fc661bf-9b32-4361-9fbf-bb04d4c02cff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09396-31 (Blood Derived Normal), aliquot CPT0502530002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2438378b-7d5a-4933-8ea5-b6148914a813

The open-access MAF lists 73 somatic variants for this specimen: 56 protein-altering or splice-affecting, 13 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 13, Frame Shift Del 2, Intron 2, 5'Flank 1, Splice Site 1, Nonsense Mutation 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC12A3 | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 56/371 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs267607050, CM021327; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.814G>C p.V272L | Missense Mutation (SNP) | VAF 51/383 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 93/321 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.4957G>T p.A1653S | Missense Mutation (SNP) | VAF 104/510 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.237); catalogued as COSV60914336; called by muse, mutect2, varscan2
- BTBD7 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 65/477 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762370810, COSV58288662; called by muse, mutect2, varscan2
- CDCP2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 55/300 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs775186450; called by muse, mutect2, varscan2
- DDRGK1 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 95/594 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754167534; called by muse, mutect2, varscan2
- GASK1A | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 38/321 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as rs796170077, COSV56183960; called by muse, mutect2, varscan2
- GRHL2 | c.568A>G p.T190A | Missense Mutation (SNP) | VAF 130/518 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs757547292; called by muse, mutect2, varscan2
- KCNQ2 | c.2006C>T p.P669L (on ENST00000359125 / NM_172107.4; = p.P641L on NM_004518.6) | Missense Mutation (SNP) | VAF 144/640 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs774306858; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEST | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 63/410 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs551376794, COSV99784043; called by muse, mutect2, varscan2
- NOSTRIN | c.692G>A p.S231N (on ENST00000317647 / NM_001039724.4; = p.S153N on NM_052946.3) | Missense Mutation (SNP) | VAF 45/376 reads (12%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV100473563; called by muse, mutect2, varscan2
- NPY2R | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 46/442 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1226583792, COSV61528466; called by muse, mutect2
- OR2AG2 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 25/522 reads (5%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.893); catalogued as COSV58455725; called by muse, mutect2
- OR4K3 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 40/319 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs897127480; called by muse, mutect2, varscan2
- PCDH9 | c.3215A>G p.E1072G (on ENST00000377865 / NM_203487.3; = p.E1038G on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/450 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100121698, COSV60526615; called by muse, mutect2, varscan2
- PCDHA3 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 77/544 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.801); catalogued as rs577444100, COSV100793406; called by muse, mutect2, varscan2
- PCDHA9 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 96/645 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as rs782259054, COSV100969988; called by muse, mutect2, varscan2
- PHRF1 | c.1772C>T p.T591I (on ENST00000264555 / NM_001286581.2; = p.T590I on NM_020901.4) | Missense Mutation (SNP) | VAF 204/786 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1167363109; called by muse, mutect2, varscan2
- RGS22 | c.211del p.I71Ffs*15 | Frame Shift Del (DEL) | VAF 44/430 reads (10%) | catalogued as rs1344877867; called by mutect2, pindel, varscan2
- RIMS1 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 98/353 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1044390019, COSV53488608; called by muse, mutect2, varscan2
- SCN7A | c.3497A>G p.N1166S | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as rs748633710; called by muse, mutect2, varscan2
- SEMA4D | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 53/620 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.466); catalogued as rs767093269, COSV59393972; called by muse, mutect2
- SH3RF3 | c.1280C>T p.S427L | Missense Mutation (SNP) | VAF 59/353 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs768730435, COSV58689522; called by muse, varscan2
- SHANK2 | c.1822G>A p.V608M | Missense Mutation (SNP) | VAF 97/360 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1260857848; called by muse, mutect2, varscan2
- TG | c.4645C>T p.R1549W | Missense Mutation (SNP) | VAF 196/614 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as rs773795717, COSV55067848; called by muse, varscan2
- TMEM132E | c.2345C>T p.P782L (on ENST00000321639; = p.P872L on NM_001304438.2) | Missense Mutation (SNP) | VAF 160/834 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs376143652; called by muse, mutect2, varscan2
- TMEM200C | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 68/569 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs1323583074; called by muse, varscan2
- WDR81 | c.5482G>A p.E1828K (on ENST00000409644 / NM_001163809.2; = p.E777K on NM_152348.4) | Missense Mutation (SNP) | VAF 112/521 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1457143497; called by muse, mutect2, varscan2
- AFDN | c.1575_1580+7del p.X525_splice | Splice Site (DEL) | VAF 23/280 reads (8%) | called by mutect2, pindel
- ANO3 | c.1709T>C p.V570A | Missense Mutation (SNP) | VAF 24/425 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.901); called by muse, mutect2
- AP000812.4 | c.169T>C p.F57L | Missense Mutation (SNP) | VAF 63/417 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BHLHE22 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 47/786 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.039); called by muse, mutect2
- BUB3 | c.82C>G p.Q28E | Missense Mutation (SNP) | VAF 101/426 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- DYNC1H1 | c.11854C>G p.Q3952E | Missense Mutation (SNP) | VAF 29/339 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- GLT1D1 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 93/378 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GPN2 | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 168/647 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- HSPA12A | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 62/390 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- LRRC53 | c.3673T>G p.S1225A | Missense Mutation (SNP) | VAF 37/370 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2
- LRTM1 | c.468C>G p.N156K | Missense Mutation (SNP) | VAF 54/313 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSS51 | c.668C>A p.P223Q | Missense Mutation (SNP) | VAF 68/398 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTHFD1L | c.2469T>G p.F823L | Missense Mutation (SNP) | VAF 66/363 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.764); called by muse, varscan2
- MUC6 | c.6451_6455del p.S2151Pfs*57 | Frame Shift Del (DEL) | VAF 162/722 reads (22%) | called by mutect2, pindel, varscan2
- NCAPG2 | c.1752G>T p.R584S | Missense Mutation (SNP) | VAF 50/362 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NPTX2 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 60/529 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NRK | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OBSCN | c.10780C>A p.Q3594K | Missense Mutation (SNP) | VAF 32/309 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- PHF20L1 | c.2991C>G p.H997Q | Missense Mutation (SNP) | VAF 159/533 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- PLXNB2 | c.4568C>T p.A1523V | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- PTPN12 | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 44/408 reads (11%) | called by muse, mutect2, varscan2
- SATB1 | c.1397C>A p.T466K | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SBNO1 | c.1691T>G p.L564R (on ENST00000420886; = p.L563R on NM_018183.5) | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- SELL | c.385G>A p.D129N (on ENST00000650983; = p.D116N on NM_000655.5) | Missense Mutation (SNP) | VAF 83/433 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TMEM241 | c.604_606del p.D202del | In Frame Del (DEL) | VAF 28/298 reads (9%) | called by mutect2, pindel, varscan2
- TRIM42 | c.1649A>C p.K550T | Missense Mutation (SNP) | VAF 50/501 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- TRPM6 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCB5 | c.864A>G p.K288= | Silent (SNP) | VAF 23/458 reads (5%) | catalogued as rs1448367366; called by muse, mutect2
- C16orf71 | c.447C>T p.G149= | Silent (SNP) | VAF 52/431 reads (12%) | catalogued as rs375548291; called by muse, mutect2, varscan2
- DST | c.10497G>A p.Q3499= | Silent (SNP) | VAF 26/335 reads (8%) | called by muse, mutect2
- F10 | c.222C>T p.S74= | Silent (SNP) | VAF 32/366 reads (9%) | called by muse, mutect2
- HIF1A | c.1023T>C p.V341= | Silent (SNP) | VAF 15/242 reads (6%) | called by muse, mutect2
- MAST2 | c.3252A>C p.S1084= | Silent (SNP) | VAF 73/431 reads (17%) | called by muse, mutect2, varscan2
- PCDHB14 | c.1476G>A p.P492= | Silent (SNP) | VAF 30/870 reads (3%) | catalogued as rs782655623; called by muse, mutect2
- PCDHGB7 | c.1419A>G p.Q473= | Silent (SNP) | VAF 70/538 reads (13%) | called by muse, mutect2, varscan2
- PKD2 | c.213C>G p.A71= | Silent (SNP) | VAF 81/534 reads (15%) | catalogued as CD141153; called by muse, mutect2, varscan2
- QTRT1 | c.174G>T p.T58= | Silent (SNP) | VAF 92/478 reads (19%) | called by muse, mutect2, varscan2
- RIMKLB | c.666A>T p.T222= | Silent (SNP) | VAF 39/317 reads (12%) | called by muse, mutect2, varscan2
- SPTY2D1OS | c.15C>A p.G5= | Silent (SNP) | VAF 18/454 reads (4%) | called by muse, mutect2
- ZNF423 | c.1545C>T p.N515= (on ENST00000563137 / NM_001379286.1; = p.N507= on NM_015069.4) | Silent (SNP) | VAF 60/503 reads (12%) | catalogued as rs1248312954; called by muse, mutect2, varscan2
- C2orf16 | chr2:27574190 C>A | 5'Flank (SNP) | VAF 39/299 reads (13%) | called by muse, mutect2, varscan2
- CLEC16A | c.2641+50T>C | Intron (SNP) | VAF 63/502 reads (13%) | catalogued as rs540404869; called by muse, mutect2, varscan2
- FRRS1L | c.-7C>T | 5'UTR (SNP) | VAF 69/559 reads (12%) | catalogued as rs1399074058; called by muse, mutect2, varscan2
- PPP4R4 | c.295-3273A>C | Intron (SNP) | VAF 56/429 reads (13%) | called by muse, mutect2, varscan2
